Somatic mutation profile of tumor specimen 0DM1JY from CCDI case PBBZTK, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 5.1 years (1,845 days).
Specimen 0DM1JY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6dac1bd-a5c9-48f5-9c08-c3d2e06ec14c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DM1JE (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/71dcd439-a73d-497f-aabe-eab4d2246f5f

The open-access MAF lists 7 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TBC1D9 | c.2677C>T p.R893C | Missense Mutation (SNP) | VAF 177/1092 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1402462741; called by muse, mutect2, varscan2
- MELK | c.1708A>G p.N570D | Missense Mutation (SNP) | VAF 41/1540 reads (3%) | SIFT tolerated (0.17); PolyPhen benign (0.084); called by muse, mutect2
- RHEB | c.110C>T p.P37L | Missense Mutation (SNP) | VAF 116/766 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- RHEB | c.109C>T p.P37S | Missense Mutation (SNP) | VAF 115/768 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- NFATC1 | c.2703C>T p.D901= (on ENST00000427363 / NM_001278669.2; = p.D888= on NM_172387.3) | Silent (SNP) | VAF 32/208 reads (15%) | catalogued as rs772022165; called by muse, mutect2, varscan2
- RHEB | c.111A>T p.P37= | Silent (SNP) | VAF 116/766 reads (15%) | called by muse, varscan2
- QARS1 | c.*47C>T | 3'UTR (SNP) | VAF 28/406 reads (7%) | called by muse, mutect2
